FM case AD782 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/46c9178b-a4f3-4e4c-8ae8-d1d08824678e

Female, 68.3 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the bone marrow. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
